Gene-level copy-number profile of tumor specimen TCGA-L5-A4OW-01A from TCGA case TCGA-L5-A4OW, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 56.9 years (20,796 days).
Specimen TCGA-L5-A4OW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.b2bdf1a2-f353-4d8c-ba61-0e85efb8ccbb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A4OW-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/275ec1e0-78e6-4ee6-a9ff-8312c3938347

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 8,445; copy number 2: 34,435; copy number 3: 11,925; copy number 4: 4,396; copy number 5: 196; copy number 6: 110; copy number 7: 32; copy number 8: 5; copy number 9: 61; copy number 10: 60; copy number 11: 17; copy number 12: 31; copy number 13: 24; copy number 14: 16; copy number 16: 1; copy number 19: 20; copy number 21: 5; copy number 22: 1; copy number 23: 1; copy number 26: 3; copy number 29: 9; copy number 30: 3; copy number 32: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A4OW-01A-11D-A28A-01): tumor purity 0.53, ploidy 2.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,703,606–59,703,703, 1 gene: MIR582.
- chr16:78,495,926–78,553,296, 4 genes: AC046158.1, AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 612 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,681,570–42,903,912, 169 genes, copy number 5–6 (broad region; genes not listed).
- chr3:88,948,142–89,048,434, 2 genes, copy number 6: ICE2P2, GAPDHP50.
- chr5:403,731–3,181,487, 73 genes, copy number 10–22 (broad region; genes not listed).
- chr6:69,672,757–72,403,143, 42 genes, copy number 6–29 (within-gene range 2–29): LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15, COL9A1, AL160262.1, AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, AL096709.1, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.2, AL035467.1, KRT19P1, RNU4-66P, RIMS1, AL035633.1.
- chr6:135,181,308–135,497,765, 7 genes, copy number 29 (within-gene range 2–29): MYB, MYB-AS1, MIR548A2, AL023693.1, AHI1, AL049552.1, AL049552.2.
- chr6:139,659,928–139,877,391, 3 genes, copy number 30: AL390205.1, FILNC1, AL050338.1.
- chr6:164,084,023–165,988,078, 13 genes, copy number 5 (within-gene range 2–5): Z97205.2, Z97205.1, Z97205.3, AL139190.1, AL358972.1, AL450345.2, AL450345.1, AL133538.1, AL136100.1, C6orf118, PDE10A, RNA5SP226, RNU6-730P.
- chr7:88,759,700–89,338,528, 1 gene, copy number 5 (within-gene range 2–5): ZNF804B.
- chr7:89,443,946–91,210,590, 22 genes, copy number 5: AC002383.1, RNU6-274P, STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3.
- chr7:92,131,774–92,245,924, 1 gene, copy number 9 (within-gene range 3–9): AC000120.3.
- chr7:92,198,969–94,066,661, 40 genes, copy number 6–9 (within-gene range 2–9): KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1.
- chr17:27,707,178–27,991,787, 9 genes, copy number 10–21 (within-gene range 2–21): AC130289.1, AC130289.2, LGALS9DP, NOS2, AC005697.1, AC005697.2, LYRM9, LINC01992, AC005697.3.
- chr17:38,419,280–39,864,312, 66 genes, copy number 9–32 (within-gene range 1–32) (broad region; genes not listed).
- chr17:41,249,687–41,930,542, 50 genes, copy number 7–13 (within-gene range 6–13): KRTAP9-4, KRTAP9-9, KRTAP9-6, KRTAP9-11P, KRTAP9-7, KRTAP9-10P, KRTAP29-1, KRTAP16-1, KRTAP17-1, TBC1D3P7, AC003958.1, KRT33A, KRT33B, KRT34, KRT31, AC003958.2, KRT41P, KRT37, KRT38, KRT43P, KRT32, RNU2-32P, KRT35, KRT36, KRT13, AC019349.1, KRT15, MIR6510, KRT19, LINC00974, KRT9, KRT14, KRT16, KRT17, KRT42P, AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11, ACLY, AC125257.2.
- chr17:43,338,741–43,720,436, 17 genes, copy number 19 (within-gene range 2–19): LINC00910, AC109326.1, RNU2-4P, RNU6-1137P, ARL4D, RNU6-470P, MIR2117HG, MIR2117, RNU6-406P, RNU6-971P, AC087650.1, DHX8, ETV4, Metazoa_SRP, MEOX1, LINC02594, WHSC1L2P.
- chr17:45,799,390–46,579,691, 23 genes, copy number 7–11 (within-gene range 2–11): MAPT-AS1, SPPL2C, MAPT, MAPT-IT1, CR936218.2, Metazoa_SRP, STH, KANSL1, CR936218.1, KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1, ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B.
- chr17:67,950,885–69,244,846, 41 genes, copy number 5–12 (within-gene range 1–12): AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1, LINC01482, AC011591.2, AC011591.1, ABCA8, ABCA9-AS1, ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804.
- chr17:70,241,324–70,629,265, 3 genes, copy number 26: CALM2P1, AC011990.1, AC005771.1.
- chr17:72,021,851–72,220,948, 3 genes, copy number 8 (within-gene range 2–8): ROCR, LINC01152, AC007461.1.
- chr17:72,072,333–72,126,416, 2 genes, copy number 8: LINC02097, SOX9.
- chr17:78,261,349–78,425,114, 7 genes, copy number 12 (within-gene range 2–12): LINC01993, AC087645.2, SOCS3, AC061992.2, RN7SL236P, PGS1, AC061992.1.
- chr18:22,088,060–23,026,488, 18 genes, copy number 6 (within-gene range 2–6): AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2.

Autosomal genes at a single copy (total copy number 1): 8,443. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
